Somatic mutation profile of tumor specimen TCGA-AA-3846-01A (aliquot TCGA-AA-3846-01A-01W-0995-10) from TCGA case TCGA-AA-3846, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 74.1 years (27,057 days).
Specimen TCGA-AA-3846-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a0707e1-3c4d-456e-be22-1b56b3fe6989.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3846-10A (Blood Derived Normal), aliquot TCGA-AA-3846-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e2e93ea-bc43-4ea1-9ebc-fe5f36bd20b6

The open-access MAF lists 99 somatic variants for this specimen: 73 protein-altering or splice-affecting, 25 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 25, Nonsense Mutation 6, Splice Site 3, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4132C>T p.Q1378* | Nonsense Mutation (SNP) | VAF 127/186 reads (68%) | hotspot (GDC flag); catalogued as rs121913329, CD1110399, CM095537, COSV57322261; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.976C>T p.R326* | Nonsense Mutation (SNP) | VAF 120/528 reads (23%) | catalogued as rs587779607, CM1412463, COSV58582838; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 27/43 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.12826G>A p.D4276N | Missense Mutation (SNP) | VAF 178/371 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs765749513, COSV68943080; called by muse, mutect2, varscan2
- ADAM12 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1475845675, COSV64111118; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3234G>T p.K1078N | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.941); catalogued as COSV99717209; called by muse, mutect2, varscan2
- ADGRA2 | c.2089G>A p.V697I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs377569553; called by muse, mutect2, varscan2
- AMIGO1 | c.1408G>A p.G470S | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV100880974, COSV63990282; called by muse, mutect2, varscan2
- APBB1 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs370357442, COSV54980818; called by muse, mutect2, varscan2
- BICRAL | c.218G>A p.S73N | Missense Mutation (SNP) | VAF 21/580 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.09); catalogued as COSV100017846; called by muse, mutect2
- BLMH | c.953A>T p.D318V | Missense Mutation (SNP) | VAF 349/922 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.298); catalogued as COSV55587274; called by muse, mutect2, varscan2
- BRINP2 | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs745487215, COSV100837859; called by muse, mutect2, varscan2
- BRWD3 | c.2359C>T p.R787C | Missense Mutation (SNP) | VAF 455/1082 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV64754297; called by muse, mutect2, varscan2
- C6orf118 | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 98/285 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV57820106; called by muse, mutect2, varscan2
- CAMK2B | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.967); catalogued as rs749755008, COSV51667434; called by muse, mutect2, varscan2
- CDH10 | c.232-2A>T p.X78_splice | Splice Site (SNP) | VAF 31/199 reads (16%) | catalogued as COSV100050222, COSV52569538; called by muse, mutect2, varscan2
- COL4A6 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 242/559 reads (43%) | catalogued as COSV57878447; called by muse, mutect2, varscan2
- CSPP1 | c.1173-2A>C p.X391_splice (on ENST00000676605; = p.X350_splice on NM_024790.6) | Splice Site (SNP) | VAF 390/1154 reads (34%) | catalogued as COSV99138056; called by muse, mutect2, varscan2
- CUBN | c.9202A>T p.I3068F | Missense Mutation (SNP) | VAF 79/357 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV100912114; called by muse, mutect2, varscan2
- CXCR2 | c.1063C>A p.H355N | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59282317; called by muse, mutect2, varscan2
- CYB5D1 | c.622A>G p.M208V | Missense Mutation (SNP) | VAF 56/99 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99640801; called by muse, mutect2, varscan2
- DIRAS2 | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 92/192 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs753119264, COSV65370009; called by muse, mutect2, varscan2
- DMD | c.5312T>A p.I1771N | Missense Mutation (SNP) | VAF 148/868 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100818373, COSV63798302; called by muse, mutect2, varscan2
- DMRTB1 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs767242421, COSV65113279; called by muse, mutect2, varscan2
- DOCK9 | c.2452T>A p.S818T (on ENST00000376460 / NM_001366676.2; = p.S819T on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/294 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV59645912; called by muse, mutect2, varscan2
- DOK5 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs749182201, COSV52817815; called by muse, mutect2, varscan2
- ESF1 | c.1914G>C p.K638N | Missense Mutation (SNP) | VAF 103/1006 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52524920; called by muse, mutect2, varscan2
- FPR1 | c.422T>A p.L141Q | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV59054120; called by muse, mutect2, varscan2
- FSTL1 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 106/364 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1174154104, COSV99820490; called by muse, mutect2, varscan2
- FSTL5 | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 262/1206 reads (22%) | catalogued as rs141917472, COSV60192986; called by muse, mutect2, varscan2
- FUT9 | c.331C>T p.R111* | Nonsense Mutation (SNP) | VAF 53/122 reads (43%) | catalogued as COSV56158420; called by muse, mutect2, varscan2
- GALNT5 | c.1342C>A p.P448T | Missense Mutation (SNP) | VAF 89/235 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV99374874; called by muse, mutect2, varscan2
- GANAB | c.205C>G p.L69V | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as COSV100647846; called by muse, mutect2, varscan2
- HEATR5B | c.833T>A p.F278Y | Missense Mutation (SNP) | VAF 193/739 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99248426; called by muse, mutect2, varscan2
- ITK | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 135/536 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs868709834, COSV101439646; called by muse, mutect2, varscan2
- KMT2C | c.5620T>G p.S1874A | Missense Mutation (SNP) | VAF 76/405 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.061); catalogued as COSV100067893; called by muse, mutect2, varscan2
- LARP4 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 215/468 reads (46%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs749476328, COSV53327601; called by muse, mutect2, varscan2
- LPCAT1 | c.604C>G p.Q202E | Missense Mutation (SNP) | VAF 191/234 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV99358777; called by muse, mutect2, varscan2
- NR2E3 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 165/423 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as rs561915025, COSV58907671; called by muse, mutect2, varscan2
- NUMBL | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs760792387, COSV53285676; called by muse, mutect2, varscan2
- OR5D14 | c.290T>G p.F97C | Missense Mutation (SNP) | VAF 124/718 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as COSV100162163; called by muse, mutect2, varscan2
- OVCH2 | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 28/548 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV71953226; called by muse, mutect2
- PCDH10 | c.1249A>G p.T417A | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs918120081, COSV99993068; called by muse, mutect2, varscan2
- PCDH17 | c.2581G>A p.A861T | Missense Mutation (SNP) | VAF 70/424 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs756164339, COSV64978238; called by muse, mutect2, varscan2
- PCDHB2 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.322); catalogued as rs1165090545, COSV50639147; called by mutect2, varscan2
- PHF8 | c.2869A>C p.T957P (on ENST00000357988 / NM_001184896.1; = p.T921P on NM_015107.3) | Missense Mutation (SNP) | VAF 65/139 reads (47%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100153852; called by muse, mutect2, varscan2
- PNPLA7 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.998); catalogued as rs200256242, COSV99480195; called by muse, mutect2, varscan2
- PRMT8 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 92/390 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV54219973, COSV99713375; called by muse, mutect2, varscan2
- PSMC4 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs1381319283, COSV50094723; called by mutect2, varscan2
- SAP30BP | c.573G>A p.W191* | Nonsense Mutation (SNP) | VAF 81/426 reads (19%) | catalogued as COSV53130580; called by muse, mutect2, varscan2
- SCN1A | c.5701G>C p.V1901L (on ENST00000303395 / NM_001202435.3; = p.V1890L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 119/530 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100319358, COSV100319463; called by muse, mutect2, varscan2
- SCN4B | c.317C>A p.S106Y | Missense Mutation (SNP) | VAF 56/878 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV61253118; called by muse, mutect2
- SLC12A2 | c.952+1G>A p.X318_splice | Splice Site (SNP) | VAF 669/2731 reads (24%) | catalogued as COSV99320617; called by muse, mutect2, varscan2
- SNUPN | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.576); catalogued as rs377184433; called by muse, mutect2, varscan2
- SPHKAP | c.1467C>A p.S489R | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs775189623, COSV60896596; called by muse, varscan2
- SPTBN1 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61688295; called by muse, mutect2, varscan2
- TAS2R30 | c.377A>G p.K126R | Missense Mutation (SNP) | VAF 53/257 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.047); catalogued as COSV67863272; called by muse, mutect2, varscan2
- TCF7L1 | c.926C>A p.A309D | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV56404040; called by muse, mutect2, varscan2
- TET3 | c.3293A>G p.N1098S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754481733, COSV69646099; called by muse, mutect2, varscan2
- TNN | c.1334G>T p.S445I | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as COSV53437404; called by muse, mutect2, varscan2
- TNS1 | c.3371G>A p.S1124N | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.054); catalogued as COSV99409931; called by muse, mutect2, varscan2
- TRPC6 | c.1561T>C p.Y521H | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100723489; called by muse, mutect2, varscan2
- TTN | c.59945A>G p.K19982R (on ENST00000591111; = p.K12558R on NM_003319.4) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | PolyPhen benign (0.104); catalogued as COSV100596505; called by muse, mutect2
- USH2A | c.12431C>T p.A4144V | Missense Mutation (SNP) | VAF 114/231 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs574981142, CD1311083, COSV100229829, COSV56330607; called by muse, mutect2, varscan2
- WNT3 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99843081; called by muse, mutect2, varscan2
- ZER1 | c.2212A>T p.T738S | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52564298, COSV99401860; called by muse, mutect2, varscan2
- ZFHX3 | c.2875G>T p.D959Y | Missense Mutation (SNP) | VAF 80/239 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51719207, COSV51740674; called by muse, mutect2, varscan2
- ZMYM6 | c.287A>C p.K96T | Missense Mutation (SNP) | VAF 65/277 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV100451545; called by muse, mutect2, varscan2
- ZNF34 | c.1453C>T p.H485Y | Missense Mutation (SNP) | VAF 34/424 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as COSV100603235; called by muse, mutect2
- ZNF479 | c.5C>A p.A2D | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100482534; called by muse, mutect2, varscan2
- ZNF518A | c.2411C>T p.T804I | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100283358; called by muse, mutect2, varscan2
- ECD | c.1463_1467del p.F488* | Frame Shift Del (DEL) | VAF 42/148 reads (28%) | called by pindel, varscan2
- INCA1 | c.240_273del p.Q81Rfs*22 (on ENST00000574617 / NM_001167986.1; = p.X67_splice on NM_213726.2) | Frame Shift Del (DEL) | VAF 35/132 reads (27%) | called by mutect2, pindel
- ESM1 | c.324G>A p.G108= | Silent (SNP) | VAF 55/232 reads (24%) | catalogued as COSV67319000; called by muse, mutect2, varscan2
- FNTB | c.627C>G p.S209= | Silent (SNP) | VAF 97/277 reads (35%) | catalogued as COSV55764760; called by muse, mutect2, varscan2
- GHITM | c.264G>A p.G88= | Silent (SNP) | VAF 102/1042 reads (10%) | catalogued as COSV64539357; called by muse, mutect2
- GPR108 | c.714C>T p.F238= | Silent (SNP) | VAF 62/136 reads (46%) | catalogued as rs768205590, COSV51188213; called by muse, mutect2, varscan2
- GPR12 | c.66G>A p.A22= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as rs1404015889, COSV67345011; called by muse, mutect2, varscan2
- IGLL5 | c.525G>A p.A175= | Silent (SNP) | VAF 67/155 reads (43%) | catalogued as rs746993194, COSV101138635, COSV101138979; called by muse, mutect2, varscan2
- KCNK15 | c.399C>T p.N133= | Silent (SNP) | VAF 11/105 reads (10%) | catalogued as rs1238075754, COSV65720927; called by muse, mutect2, varscan2
- KIF2B | c.1281A>T p.A427= | Silent (SNP) | VAF 58/274 reads (21%) | catalogued as COSV52136312; called by muse, mutect2
- LAMC3 | c.3729C>T p.G1243= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs199639870, COSV62655120; called by muse, mutect2, varscan2
- LRRC2 | c.129A>T p.I43= | Silent (SNP) | VAF 100/197 reads (51%) | catalogued as COSV56129201; called by muse, mutect2, varscan2
- MEGF8 | c.6552C>T p.N2184= (on ENST00000251268 / NM_001271938.2; = p.N2117= on NM_001410.3) | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs773339356, COSV52103999; called by muse, mutect2, varscan2
- PCBP3 | c.1032G>A p.T344= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs760592011, COSV68408747; called by muse, mutect2, varscan2
- PCDHGB2 | c.2304G>A p.L768= | Silent (SNP) | VAF 51/67 reads (76%) | catalogued as COSV54047945; called by muse, mutect2, varscan2
- PHF14 | c.1113T>G p.P371= | Silent (SNP) | VAF 136/5080 reads (3%) | catalogued as COSV101301770; called by muse, mutect2
- PLPP3 | c.285T>A p.I95= | Silent (SNP) | VAF 107/489 reads (22%) | catalogued as COSV64840884; called by muse, mutect2, varscan2
- RTTN | c.4983C>T p.L1661= | Silent (SNP) | VAF 56/253 reads (22%) | catalogued as rs1397253498, COSV55353481; called by muse, mutect2, varscan2
- SCN1A | c.2625G>A p.T875= (on ENST00000303395 / NM_001202435.3; = p.T864= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as rs990811788, COSV57690845; called by muse, mutect2, varscan2
- SYMPK | c.1551G>A p.P517= | Silent (SNP) | VAF 102/223 reads (46%) | catalogued as rs566434106, COSV55616397; called by muse, mutect2, varscan2
- TACC2 | c.5131C>T p.L1711= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as COSV57775775; called by muse, mutect2, varscan2
- TBC1D2 | c.1440G>A p.K480= | Silent (SNP) | VAF 34/378 reads (9%) | catalogued as COSV100579720; called by muse, mutect2
- TRNT1 | c.390C>T p.T130= | Silent (SNP) | VAF 13/296 reads (4%) | catalogued as COSV99285563; called by muse, mutect2
- TTN | c.3714T>G p.T1238= (on ENST00000591111; = p.T1192= on NM_003319.4) | Silent (SNP) | VAF 191/892 reads (21%) | catalogued as COSV59950710, COSV60107421, COSV60194267; called by muse, mutect2, varscan2
- VPS13B | c.7119G>A p.V2373= | Silent (SNP) | VAF 194/505 reads (38%) | catalogued as COSV62159602; called by muse, mutect2, varscan2
- WDR5B | c.300T>A p.S100= | Silent (SNP) | VAF 52/100 reads (52%) | catalogued as COSV58073178; called by muse, mutect2, varscan2
- ZNF786 | c.420C>T p.S140= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV60277822; called by muse, mutect2, varscan2
- TP53AIP1 | c.141+80A>G | Intron (SNP) | VAF 13/43 reads (30%) | catalogued as COSV71688943; called by muse, mutect2, varscan2
